Gene-level copy-number profile of tumor specimen C3L-00993-01 from CPTAC case C3L-00993, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.6 years (27,610 days).
Specimen C3L-00993-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12769902-678c-4575-8a4f-acf7d776b45c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00993-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/072d7263-be64-4f6b-be52-5396fd635494

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,316; copy number 2: 23,462; copy number 3: 15,498; copy number 4: 11,272; copy number 5: 2,222; copy number 6: 1,429; copy number 7: 765; copy number 8: 656; copy number 9: 6; copy number 10: 59; copy number 11: 3; copy number 12: 9; copy number 13: 11; copy number 14: 36; copy number 15: 11; copy number 19: 10; copy number 20: 42; copy number 21: 4; copy number 22: 9; copy number 26: 4; copy number 27: 1; copy number 30: 4; copy number 40: 38; copy number 82: 13; copy number 137: 10.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:60,304,047–60,702,010, 10 genes (within-gene range 0–1): RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,263 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:58,159,243–66,200,373, 156 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:77,652,025–78,438,921, 7 genes, copy number 6: AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1.
- chr3:93,843,764–112,362,812, 233 genes, copy number 5 (broad region; genes not listed).
- chr3:171,058,414–171,460,408, 1 gene, copy number 6 (within-gene range 4–6): TNIK.
- chr3:171,439,526–198,123,232, 522 genes, copy number 6–8 (broad region; genes not listed).
- chr5:58,198–7,219,291, 134 genes, copy number 6 (broad region; genes not listed).
- chr5:7,287,924–45,895,970, 544 genes, copy number 6–9 (broad region; genes not listed).
- chr5:153,887,428–155,018,141, 29 genes, copy number 5: LINC01861, AC091962.1, FAM114A2, MFAP3, GALNT10, SAP30L-AS1, HNRNPA3P7, AC008625.1, MIR1294, RN7SL655P, SAP30L, HAND1, AC026688.2, AC026688.1, CIR1P1, MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B.
- chr6:21,354,411–22,654,455, 12 genes, copy number 5 (within-gene range 3–5): AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL.
- chr7:80,742,538–91,556,848, 97 genes, copy number 5 (broad region; genes not listed).
- chr7:106,090,505–109,999,624, 56 genes, copy number 5: SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8.
- chr7:110,215,891–110,216,380, 1 gene, copy number 5: AC073114.2.
- chr8:36,277,763–43,674,591, 184 genes, copy number 8–40 (broad region; genes not listed).
- chr8:58,805,412–59,119,147, 1 gene, copy number 5 (within-gene range 3–5): TOX.
- chr8:58,991,720–134,881,899, 1,078 genes, copy number 5–8 (broad region; genes not listed).
- chr11:91,794,319–93,288,903, 25 genes, copy number 5: LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2.
- chr14:22,105,343–23,376,403, 147 genes, copy number 6–11 (broad region; genes not listed).
- chr14:34,752,731–38,041,442, 73 genes, copy number 7–137 (within-gene range 4–137) (broad region; genes not listed).
- chr14:72,926,377–76,310,066, 124 genes, copy number 5–7 (broad region; genes not listed).
- chr16:23,017,723–25,454,647, 64 genes, copy number 6–8 (within-gene range 6–11) (broad region; genes not listed).
- chr18:21,928,985–27,595,164, 105 genes, copy number 5–6 (broad region; genes not listed).
- chr20:30,377,372–51,905,030, 575 genes, copy number 5 (broad region; genes not listed).
- chr20:54,859,688–64,327,972, 255 genes, copy number 6 (broad region; genes not listed).
- chr22:15,282,557–33,922,841, 840 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
